Somatic mutation profile of tumor specimen MMRF_2808_1_BM_CD138pos (aliquot MMRF_2808_1_BM_CD138pos_T1_KHS5U_L15742) from MMRF case MMRF_2808, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 62.5 years (22,846 days).
Specimen MMRF_2808_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1be206a0-0d3e-4321-813b-5989ebc63501.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2808_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2808_1_PB_WBC_C3_KHS5U_L15786; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f1bd57d-e078-4d08-9b43-8ffab0797757

The open-access MAF lists 82 somatic variants for this specimen: 37 protein-altering or splice-affecting, 6 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, 3'UTR 19, Intron 12, Silent 6, 5'UTR 4, RNA 3, Frame Shift Ins 2, Splice Site 2, Nonsense Mutation 2, 5'Flank 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DIS3 | c.1463A>C p.D488A | Missense Mutation (SNP) | VAF 60/217 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66706118, COSV66708289; called by muse, mutect2, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 33/84 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2420G>A p.R807H | Missense Mutation (SNP) | VAF 104/209 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as rs141414377; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- AIPL1 | c.281C>T p.T94M | Missense Mutation (SNP) | VAF 71/151 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs773203055; called by muse, mutect2, varscan2
- DLGAP1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 98/221 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316366739; called by muse, mutect2, varscan2
- DNMT3A | c.2196dup p.E733* | Frame Shift Ins (INS) | VAF 22/70 reads (31%) | catalogued as rs771906613; called by mutect2, pindel, varscan2
- IGLV3-1 | c.65A>C p.E22A | Missense Mutation (SNP) | VAF 112/364 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.018); catalogued as rs528877557; called by muse, varscan2
- KIAA0930 | c.731G>A p.R244H (on ENST00000336156 / NM_001009880.2; = p.R249H on NM_015264.2) | Missense Mutation (SNP) | VAF 91/205 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs369518786; called by muse, mutect2, varscan2
- MUC16 | c.32858C>A p.T10953N | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as rs982819061; called by muse, mutect2, varscan2
- RESF1 | c.1835A>G p.D612G | Missense Mutation (SNP) | VAF 76/160 reads (48%) | SIFT tolerated (0.46); PolyPhen benign (0.062); catalogued as rs1408774456; called by muse, mutect2, varscan2
- RNF213 | c.8795T>C p.F2932S | Missense Mutation (SNP) | VAF 97/240 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs148301460; called by muse, mutect2, varscan2
- RPTOR | c.2622G>A p.A874= | Splice Region (SNP) | VAF 19/142 reads (13%) | catalogued as rs766200096; called by muse, mutect2, varscan2
- SLC14A2 | c.458C>G p.T153R | Missense Mutation (SNP) | VAF 35/59 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.625); catalogued as COSV54906382; called by muse, mutect2, varscan2
- TENM2 | c.2317C>T p.R773C (on ENST00000518659 / NM_001122679.2; = p.R541C on NM_001080428.3) | Missense Mutation (SNP) | VAF 54/124 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.836); catalogued as rs372765674, COSV69123862; called by muse, varscan2
- WNT10A | c.880T>G p.F294V | Missense Mutation (SNP) | VAF 31/73 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as rs758566891, COSV51463519; called by muse, mutect2, varscan2
- AAR2 | c.745dup p.Q249Pfs*6 | Frame Shift Ins (INS) | VAF 11/61 reads (18%) | called by mutect2, pindel
- ACTG1 | c.65C>A p.A22D | Missense Mutation (SNP) | VAF 163/339 reads (48%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.447); called by muse, varscan2
- ATOH1 | c.70C>T p.Q24* | Nonsense Mutation (SNP) | VAF 63/145 reads (43%) | called by muse, mutect2, varscan2
- C12orf60 | c.85G>C p.V29L | Missense Mutation (SNP) | VAF 94/207 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- CACNA2D1 | c.2990G>A p.G997E (on ENST00000356253 / NM_001366867.1; = p.G985E on NM_000722.4) | Missense Mutation (SNP) | VAF 24/56 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC172 | c.742-1G>A p.X248_splice | Splice Site (SNP) | VAF 62/131 reads (47%) | called by muse, mutect2, varscan2
- CTNND2 | c.3377A>G p.N1126S | Missense Mutation (SNP) | VAF 49/98 reads (50%) | SIFT tolerated (0.67); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- DAB2 | c.2258C>T p.S753F | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT tolerated (0.53); PolyPhen benign (0.006); called by muse, mutect2
- EPB41L1 | c.2371G>A p.V791I | Missense Mutation (SNP) | VAF 50/82 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- GABRG1 | c.1035del p.F345Lfs*4 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- HMGB1 | c.133T>A p.C45S | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- IGKV1-33 | c.7A>T p.M3L | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.029); called by muse, mutect2
- MAPK14 | c.113T>C p.V38A | Missense Mutation (SNP) | VAF 80/152 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- MPDZ | c.749T>C p.V250A | Missense Mutation (SNP) | VAF 136/288 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- NELL1 | c.1192G>A p.G398R | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NUDT19 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- RFC2 | c.460T>G p.L154V (on ENST00000055077 / NM_181471.3; = p.L120V on NM_002914.4) | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- SCAF8 | c.904C>T p.Q302* | Nonsense Mutation (SNP) | VAF 90/196 reads (46%) | called by muse, mutect2, varscan2
- SLIT2 | c.1130+1G>C p.X377_splice | Splice Site (SNP) | VAF 39/87 reads (45%) | called by muse, mutect2, varscan2
- SMIM7 | c.32T>C p.L11S | Missense Mutation (SNP) | VAF 93/179 reads (52%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SOX1 | c.287A>C p.E96A | Missense Mutation (SNP) | VAF 90/181 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- STON2 | c.136T>G p.S46A | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ACTG1 | c.66T>A p.A22= | Silent (SNP) | VAF 159/332 reads (48%) | called by muse, varscan2
- ENO4 | c.393G>T p.A131= (on ENST00000622726; = p.A130= on NM_001242699.2) | Silent (SNP) | VAF 27/189 reads (14%) | called by muse, mutect2, varscan2
- HIPK2 | c.627G>A p.T209= | Silent (SNP) | VAF 10/254 reads (4%) | catalogued as rs1305999098; called by muse, mutect2
- NCL | c.1092G>A p.L364= | Silent (SNP) | VAF 70/157 reads (45%) | called by muse, mutect2, varscan2
- TNS1 | c.1047C>T p.G349= | Silent (SNP) | VAF 33/249 reads (13%) | called by muse, mutect2, varscan2
- ZNF529 | c.1050T>C p.S350= | Silent (SNP) | VAF 54/122 reads (44%) | called by muse, mutect2, varscan2
- ABHD17B | c.*138G>A | 3'UTR (SNP) | VAF 37/83 reads (45%) | catalogued as rs1413875657; called by muse, mutect2, varscan2
- AC064807.1 | n.2735G>A | RNA (SNP) | VAF 26/199 reads (13%) | called by muse, mutect2, varscan2
- AC073254.1 | n.1132-248G>A | Intron (SNP) | VAF 96/186 reads (52%) | called by muse, mutect2, varscan2
- AMER1 | c.*4486A>G | 3'UTR (SNP) | VAF 11/79 reads (14%) | called by muse, mutect2, varscan2
- AQP5 | c.*191C>T | 3'UTR (SNP) | VAF 8/146 reads (5%) | catalogued as rs1299016990; called by muse, mutect2
- ASPH | c.976+12384T>G | Intron (SNP) | VAF 24/41 reads (59%) | called by muse, mutect2, varscan2
- BBS9 | c.*195G>T | 3'UTR (SNP) | VAF 66/112 reads (59%) | called by muse, mutect2, varscan2
- BMP3 | c.*1019C>T | 3'UTR (SNP) | VAF 42/107 reads (39%) | called by muse, mutect2, varscan2
- C1orf122 | chr1:37807360 G>A | 5'Flank (SNP) | VAF 25/45 reads (56%) | called by muse, mutect2, varscan2
- C1orf158 | c.*212G>A | 3'UTR (SNP) | VAF 45/108 reads (42%) | called by muse, mutect2, varscan2
- CAPZA2 | c.40-7987A>G | Intron (SNP) | VAF 46/92 reads (50%) | called by muse, mutect2, varscan2
- CLIP1 | c.3966+601T>C | Intron (SNP) | VAF 24/52 reads (46%) | called by muse, mutect2, varscan2
- CUX1 | c.31-2973_31-2970dup | Intron (INS) | VAF 24/63 reads (38%) | called by mutect2, varscan2
- ERMN | c.*1567A>G | 3'UTR (SNP) | VAF 29/82 reads (35%) | catalogued as rs1275142657; called by muse, mutect2, varscan2
- ESPNP | n.938T>C | RNA (SNP) | VAF 27/83 reads (33%) | called by muse, mutect2, varscan2
- FBLN5 | c.990-320G>A | Intron (SNP) | VAF 47/105 reads (45%) | catalogued as rs1333432140; called by muse, mutect2
- FGFR2 | c.*661del | 3'UTR (DEL) | VAF 8/52 reads (15%) | catalogued as rs533680275; called by mutect2, varscan2
- GPRC5A | c.*3464A>T | 3'UTR (SNP) | VAF 32/54 reads (59%) | called by muse, mutect2, varscan2
- HGS | c.1180-16C>T | Intron (SNP) | VAF 42/95 reads (44%) | called by muse, mutect2, varscan2
- IGLL5 | c.-79G>A | 5'UTR (SNP) | VAF 98/148 reads (66%) | catalogued as rs551309597; called by muse, mutect2, varscan2
- KPNA4 | c.-239C>T | 5'UTR (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- LIMK1 | c.*1097A>G | 3'UTR (SNP) | VAF 8/228 reads (4%) | called by muse, mutect2
- LINC02860 | n.214T>C | RNA (SNP) | VAF 120/269 reads (45%) | called by muse, mutect2, varscan2
- LIPH | c.*322C>T | 3'UTR (SNP) | VAF 136/274 reads (50%) | catalogued as rs757804825; called by muse, mutect2, varscan2
- MED20 | c.-90T>C | 5'UTR (SNP) | VAF 101/270 reads (37%) | called by muse, varscan2
- MME | c.*955G>A | 3'UTR (SNP) | VAF 59/118 reads (50%) | called by muse, mutect2, varscan2
- NAA30 | c.*958A>G | 3'UTR (SNP) | VAF 26/60 reads (43%) | catalogued as rs991245918; called by mutect2, varscan2
- NOBOX | c.210+891del | Intron (DEL) | VAF 85/187 reads (45%) | called by mutect2, pindel, varscan2
- NSUN7 | c.-65C>T | 5'UTR (SNP) | VAF 50/119 reads (42%) | catalogued as COSV100349687; called by muse, mutect2, varscan2
- PROC | c.*246G>A | 3'UTR (SNP) | VAF 49/100 reads (49%) | called by muse, mutect2, varscan2
- RRM2 | c.435+82T>C | Intron (SNP) | VAF 100/190 reads (53%) | catalogued as rs1558379327; called by muse, mutect2, varscan2
- SBK1 | c.*188G>A | 3'UTR (SNP) | VAF 56/94 reads (60%) | catalogued as rs1000384268; called by muse, mutect2, varscan2
- SCN9A | c.377+84T>G | Intron (SNP) | VAF 8/19 reads (42%) | called by mutect2, varscan2
- SCRN1 | c.*1714A>G | 3'UTR (SNP) | VAF 42/86 reads (49%) | catalogued as rs905815563; called by muse, mutect2, varscan2
- SFMBT2 | c.525+496_525+497del | Intron (DEL) | VAF 54/115 reads (47%) | catalogued as rs982808529; called by mutect2, varscan2
- SHCBP1 | c.1465-38A>G | Intron (SNP) | VAF 39/84 reads (46%) | called by muse, mutect2, varscan2
- SLC17A5 | c.*370G>A | 3'UTR (SNP) | VAF 55/105 reads (52%) | called by muse, mutect2, varscan2
- SULT1C2 | c.*293A>G | 3'UTR (SNP) | VAF 54/121 reads (45%) | called by muse, mutect2, varscan2
- SUSD5 | c.*1105T>A | 3'UTR (SNP) | VAF 8/78 reads (10%) | called by muse, mutect2, varscan2
